Surgical pathology report (de-identified scan), TCGA case TCGA-QC-A6FX, project TCGA-SARC (Sarcoma), tissue source site Emory University, specimen TCGA-QC-A6FX-01A (Primary Tumor).

[page 1 of 4]
-Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:
Contributor system:

* Final Report *

ICD-0-3
Sarcoma, pleomorphic (8802/3)
undifferentiated (8805/3)
Coded to highest 8805/3
Site C6CF Soft tissue trunk NOS C49.6
path Soft tissue back C49.6
9/06/11/13

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender:

M

(Age:

Acc #:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. SKIN AND SOFT TISSUE, LEFT BACK, RADICAL RESECTION:

- PLEOMORPHIC UNDIFFERENTIATED SARCOMA, HIGH GRADE.
- SARCOMA INVOLVES THE DEEP, SUPERIOR, AND INFERIOR RESECTION MARGINS.
- PREVIOUS BIOPSY SITE CHANGES.
- SEE SYNOPTIC REPORT.

B. SOFT TISSUE, ADDITIONAL DEEP MARGIN, EXCISION:

- BENIGN SKELETAL MUSCLE.
- NO TUMOR IS IDENTIFIED.

C. SOFT TISSUE, ADDITIONAL MARGIN AT SITE OF SUSPECTED SECONDARY NODULE, EXCISION:

- BENIGN SKELETAL MUSCLE.
- NO TUMOR IS IDENTIFIED.

Printed by:

Printed on:

Page 1 of 4
(Continued)

Transcription Discrepancy		
Metastatic Discrepancy		
Final Malignancy History		
Discrepancy Primary Tumor		
Site (circle):		

9/24/13

[page 2 of 4]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Assisted by:

Synoptic Worksheet

A. Radical resection, left back, high grade sarcoma, short - superior; long - lateral; white - secondary nodule (suspected):

Preresection Treatment:	No therapy
Procedure:	Radical resection
Tumor Site:	Left back
Histologic Type:	Pleomorphic undifferentiated sarcoma
Histologic Grade:	Grade 3
Macroscopic Extent of Tumor:	Deep - Intramuscular
Tumor Size:	Greatest dimepsion: 5.0 cm Additional Dimension: 2.4 cm Additional Dimension: 1.5 cm
Margins:	Margin(s) positive for sarcoma Margin(s): Inferior (green), Slide A3; Superior (blue), Slide A5
Mitotic Rate:	12 /10 high-power fields (HPF)
Necrosis:	Present Extent: 10%
Treatment Effect:	Not identified
Immunohistochemistry:	Not performed
Cytogenetics:	Not performed
Molecular Pathology:	Not performed
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2a: Tumor more than 5 cm in greatest dimension, superficial tumor
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Number of nodes examined: 0 Number of nodes positive: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None

Clinical History

Sarcoma on back. Wide local excision sarcoma, left back.

Specimen(s) Received

A: Radical resection, left back, high grade sarcoma, short - superior; long - lateral; white - secondary nodule (suspected)

Printed by:

Printed on:

[page 3 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

B: Additional deep margin at site of dominant tumor

C: Additional margin at site of suspected secondary nodule

Gross Description

Specimen A is received fresh in a container labeled with the patient's name and designated "sarcoma, left back" and consists of an excision of white skin and underlying subcutaneous tissue measuring 9.5 x 3.9 cm excised to a depth of 4.8 cm. The skin ellipse itself measures 9.0 x 2.5 cm and has a centrally-located, well-healed linear scar measuring 6.7 x 0.1 cm with the long axis oriented parallel to the long axis of the ellipse. The deepest portion of the specimen appears to be skeletal muscle, measuring approximately 7.0 x 4.8 cm with a thickness of up to 1.6 cm. The specimen is oriented with a double long suture on one tip of the ellipse designated lateral and a short suture on one side designating superior. Additionally there is a white suture on the inferior-deep aspect which designates a suspected secondary nodule. On cross section there is a rubbery firm tan-white ovoid mass located within the skeletal muscle measuring approximately 5.0 x 2.4 x 1.5 cm with no definite necrosis. This mass appears to abut the deep margin as well as the deep aspect of the superior and inferior margins and comes within less than 1.0 mm of the deep aspect of the lateral margin, while it is approximately 2.7 cm from the medial margin and 3.7 cm deep to the skin surface. The secondary nodule indicated by the white suture measures 1.8 x 1.5 x 1.0 cm but appears to merge with the main mass and is included in the aforementioned margin measurements. Deep to the skin surface on the medial half there is a cystic cavity measuring 2.0 x 1.4 x 1.3 cm, which may represent a prior surgical site cavity. No other lesions are identified. The specimen is inked as follows: superior, blue; inferior, green; medial, red; lateral, yellow; deep, black. The margin adjacent to the suspected secondary nodule along the central inferior-deep aspect is inked orange. A portion of tumor and normal tissue are given to Representative sections are submitted as follows. (Dictated by

Specimen B is received fresh in a container labeled with the patient's name and designated "additional deep margin at tumor" and consists of an unoriented portion of apparent skeletal muscle measuring 2.1 x 1.9 x 1.1 cm. One of the narrow edges appears to be cauterized; this edge is inked blue and the remaining external surface of the specimen is inked green. No tumor is identified. The specimen is serially sectioned perpendicular to the cauterized edge and submitted entirely in cassettes "B1" and "B2." (Dictated by

Specimen C is received fresh in a container labeled with the patient's name and designated "additional margin at nodule" and consists of an irregularly-shaped unoriented portion of apparent skeletal muscle measuring 1.4 x 1.3 x 0.5 cm. One edge appears to be cauterized; this edge is inked orange and the remaining external surfaces are inked green. No tumor is identified. The specimen is serially sectioned perpendicular to the cauterized edge and entirely submitted in cassettes "C1" and "C2." (Dictated by

CASSETTE SUMMARY:

A1:	Tumor to closest deep and inferior margins
A2:	Additional tumor to deep
A3:	Secondary nodule in relation to inferior and deep margins and main mass
A4:	Tumor to deep aspect of superior margin
A5:	Additional tumor to deep aspect of superior margin
A6,7:	Tumor to deep aspect of lateral margin
A8:	Representative medial margin
A9:	Representative skin with scar and underlying cavity
A10-13:	Additional representative sections of tumor

Printed by:
Printed on:

[page 4 of 4]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file a2b645cd-8728-4f26-85c3-f0bfdf76dccd (TCGA-QC-A6FX.7139C84F-6B44-4912-AB90-6F4B2877C41B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).